Somatic mutation profile of tumor specimen C3N-01761-01 (aliquot CPT0116710006) from CPTAC case C3N-01761, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 69.1 years (25,238 days).
Specimen C3N-01761-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 686124a1-48a5-4fd6-8c69-1ba72e75b0ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01761-31 (Blood Derived Normal), aliquot CPT0116770002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e0fd6f7-a31d-4b86-aa87-8f13c592648e

The open-access MAF lists 820 somatic variants for this specimen: 569 protein-altering or splice-affecting, 136 silent, 115 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 354, Silent 136, Frame Shift Del 115, Intron 59, Frame Shift Ins 49, Splice Region 19, 3'UTR 17, Nonsense Mutation 15, RNA 15, 5'UTR 13, In Frame Del 9, 3'Flank 7.

Variants (750 of 820; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOA1 | c.85dup p.Q29Pfs*30 | Frame Shift Ins (INS) | VAF 42/118 reads (36%) | catalogued as rs753348565; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CAPN3 | c.1795dup p.T599Nfs*33 | Frame Shift Ins (INS) | VAF 28/133 reads (21%) | catalogued as rs80338803; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- CLCN4 | c.2051C>T p.P684L | Missense Mutation (SNP) | VAF 205/543 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs1246068842; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 132/454 reads (29%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- DLD | c.633dup p.V212Sfs*32 | Frame Shift Ins (INS) | VAF 44/194 reads (23%) | catalogued as rs1040811473; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- FGFR2 | c.1144T>C p.C382R | Missense Mutation (SNP) | VAF 291/408 reads (71%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs121913474, COSV60638681, COSV60642677; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- HNF1B | c.1561del p.Q521Sfs*70 | Frame Shift Del (DEL) | VAF 108/365 reads (30%) | catalogued as rs764042837; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 68/220 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs121913294, CM074465, CM102472, COSV100911374, COSV64288961, COSV64302184; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 46/202 reads (23%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 31/119 reads (26%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SACS | c.8793dup p.R2932Tfs*7 | Frame Shift Ins (INS) | VAF 14/53 reads (26%) | catalogued as rs767871841; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ZFP57 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 107/331 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs77625743, CM083210, COSV65306439; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAD9 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as rs754712413; called by muse, mutect2, varscan2
- ACOX3 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs765630911, COSV62711508; called by muse, mutect2, varscan2
- ACSM2B | c.817C>G p.L273V | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.065); catalogued as COSV100312822; called by muse, mutect2, varscan2
- ADCK5 | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 18/505 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58233397, COSV58233509; called by muse, mutect2
- ADRA2B | c.636del p.P213Lfs*140 | Frame Shift Del (DEL) | VAF 100/469 reads (21%) | catalogued as rs756613487; called by mutect2, pindel, varscan2
- AFDN | c.4812+11dup | Splice Region (INS) | VAF 48/168 reads (29%) | catalogued as rs760964511; called by mutect2, pindel, varscan2
- AGPAT4 | c.907dup p.R303Pfs*60 | Frame Shift Ins (INS) | VAF 40/134 reads (30%) | catalogued as rs750826126; called by mutect2, varscan2
- AJAP1 | c.1162C>T p.R388* | Nonsense Mutation (SNP) | VAF 52/137 reads (38%) | catalogued as COSV65452928; called by muse, mutect2, varscan2
- AKIRIN1 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated, low confidence (0.42); PolyPhen probably damaging (0.946); catalogued as rs998356660; called by muse, mutect2, varscan2
- ALG1 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 187/684 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.389); catalogued as rs748038529; called by muse, mutect2, varscan2
- AMER3 | c.611del p.P204Rfs*62 | Frame Shift Del (DEL) | VAF 28/196 reads (14%) | catalogued as COSV100365971, COSV58465768; called by mutect2, pindel, varscan2
- AMH | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs897509730, CM153695; called by muse, mutect2
- APBA1 | c.2401del p.H801Tfs*17 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as COSV55228718, COSV99596038; called by mutect2, pindel, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | catalogued as rs749401724; called by mutect2, varscan2
- ARHGAP4 | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 144/380 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs782781360; called by muse, mutect2, varscan2
- ARHGEF10 | c.649G>A p.A217T (on ENST00000398564; = p.A192T on NM_014629.4) | Missense Mutation (SNP) | VAF 158/437 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.012); catalogued as rs779899466, COSV50649026; called by muse, mutect2, varscan2
- ASB2 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 77/203 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.456); catalogued as rs1294936549; called by muse, mutect2, varscan2
- ASH1L | c.2148A>C p.K716N | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV64206634; called by muse, mutect2, varscan2
- ASXL3 | c.6110del p.P2037Hfs*43 | Frame Shift Del (DEL) | VAF 32/87 reads (37%) | catalogued as rs747712363; called by mutect2, varscan2
- ATP6V1B1 | c.552del p.I185Sfs*23 | Frame Shift Del (DEL) | VAF 59/236 reads (25%) | catalogued as COSV52268896; called by mutect2, pindel, varscan2
- ATXN1L | c.1623dup p.E542Rfs*47 | Frame Shift Ins (INS) | VAF 121/396 reads (31%) | catalogued as rs775793808; called by mutect2, pindel, varscan2
- BAHD1 | c.755T>C p.V252A | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779929304; called by muse, mutect2, varscan2
- BEGAIN | c.1558del p.D520Tfs*57 | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | catalogued as rs749168305; called by mutect2, varscan2
- BEND3 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 149/427 reads (35%) | catalogued as COSV99068813; called by muse, mutect2, varscan2
- BLM | c.998A>G p.D333G | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs772415449; called by muse, mutect2, varscan2
- BRCC3 | c.549-2A>C p.X183_splice | Splice Site (SNP) | VAF 87/220 reads (40%) | catalogued as COSV100341485; called by muse, mutect2, varscan2
- BRSK2 | c.1738C>G p.P580A | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV57546011; called by muse, mutect2, varscan2
- BRWD3 | c.2888C>T p.S963L | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.069); catalogued as COSV64751280; called by muse, mutect2, varscan2
- CA2 | c.440del p.L147* | Frame Shift Del (DEL) | VAF 129/491 reads (26%) | catalogued as rs763603775; called by mutect2, pindel, varscan2
- CA8 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 84/400 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as rs746839542, COSV58771225; called by muse, mutect2, varscan2
- CACNA1H | c.3529G>A p.D1177N | Missense Mutation (SNP) | VAF 126/418 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as rs746877235; called by muse, mutect2, varscan2
- CACNB3 | c.472+13del | Splice Region (DEL) | VAF 21/76 reads (28%) | catalogued as rs778256532; called by mutect2, pindel, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 56/118 reads (47%) | catalogued as rs762770988, COSV62756627; called by mutect2, varscan2
- CBFA2T2 | c.1321dup p.T441Nfs*7 | Frame Shift Ins (INS) | VAF 50/133 reads (38%) | catalogued as rs1170461056; called by mutect2, varscan2
- CCAR2 | c.2315C>A p.P772H | Missense Mutation (SNP) | VAF 57/306 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV52383632; called by muse, mutect2, varscan2
- CCDC102A | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1413327021; called by muse, mutect2, varscan2
- CCDC150 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 26/126 reads (21%) | catalogued as rs760076975, COSV55876633; called by muse, mutect2, varscan2
- CCDC88B | c.2375G>A p.R792Q | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs761333552, COSV57266306; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 48/158 reads (30%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH10 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 66/206 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760208493, COSV52594806; called by muse, mutect2, varscan2
- CDNF | c.466del p.E156Rfs*13 | Frame Shift Del (DEL) | VAF 86/281 reads (31%) | catalogued as COSV101012365; called by mutect2, varscan2
- CELSR3 | c.5802del p.S1935Afs*4 | Frame Shift Del (DEL) | VAF 30/99 reads (30%) | catalogued as rs1205203585, COSV50840268; called by mutect2, pindel, varscan2
- CFAP46 | c.2046dup p.E683Rfs*13 | Frame Shift Ins (INS) | VAF 29/96 reads (30%) | catalogued as rs1339296916; called by mutect2, varscan2
- CFTR | c.2615C>T p.A872V | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs145714303, CD067857; called by muse, mutect2
- CHERP | c.2566G>A p.G856S | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1235881782; called by muse, mutect2, varscan2
- CHSY1 | c.666dup p.P223Afs*29 | Frame Shift Ins (INS) | VAF 38/106 reads (36%) | catalogued as rs762321510; called by mutect2, varscan2
- CIITA | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 136/404 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs375474357, COSV100161644; called by muse, mutect2, varscan2
- CLDN34 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 78/244 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs776584207, COSV71357032; called by muse, mutect2, varscan2
- CLEC2B | c.349A>G p.M117V | Missense Mutation (SNP) | VAF 87/277 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1382795606; called by muse, mutect2, varscan2
- CNNM1 | c.2789G>T p.R930M | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs757625485; called by muse, mutect2, varscan2
- CNTNAP2 | c.2191G>A p.G731S | Missense Mutation (SNP) | VAF 174/683 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as rs369867547, CM080157; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTRL | c.6361C>T p.R2121C | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs531981372, COSV53053959; called by muse, mutect2, varscan2
- COL22A1 | c.1622del p.P541Lfs*9 | Frame Shift Del (DEL) | VAF 69/239 reads (29%) | catalogued as rs1563754947, COSV57325891; called by mutect2, pindel, varscan2
- COL7A1 | c.5171G>A p.R1724H | Missense Mutation (SNP) | VAF 110/372 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as rs146154014; called by muse, mutect2, varscan2
- COL8A2 | c.281del p.P94Lfs*143 | Frame Shift Del (DEL) | VAF 41/149 reads (28%) | catalogued as rs1277273445; called by mutect2, pindel, varscan2
- COL9A2 | c.1242del p.G415Efs*116 | Frame Shift Del (DEL) | VAF 65/266 reads (24%) | catalogued as rs756694568; ClinVar: uncertain significance; called by mutect2, varscan2
- CP | c.252A>G p.I84M | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs757449784; called by muse, mutect2, varscan2
- CPTP | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 100/309 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.832); catalogued as rs759718470; called by muse, mutect2, varscan2
- CR1 | c.5548C>T p.H1850Y | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1558272577; called by muse, mutect2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 159/504 reads (32%) | catalogued as rs747832403; called by mutect2, varscan2
- CRELD1 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 134/452 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs760576379; called by muse, mutect2, varscan2
- CRISP3 | c.145T>G p.F49V (on ENST00000371159 / NM_001368123.1; = p.F31V on NM_006061.4) | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.083); catalogued as COSV53822690; called by muse, mutect2, varscan2
- CXCR6 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 94/254 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs771676006, COSV56115534; called by muse, mutect2, varscan2
- CYP2E1 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs767486762, COSV99428917, COSV99429175; called by muse, mutect2, varscan2
- DAPK1 | c.3510G>T p.W1170C | Missense Mutation (SNP) | VAF 83/256 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100800921; called by muse, mutect2, varscan2
- DDX49 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as rs775026871; called by muse, mutect2, varscan2
- DDX60L | c.4925del p.N1642Mfs*9 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | catalogued as rs773554787; called by mutect2, pindel, varscan2
- DENND1B | c.1104G>A p.M368I | Missense Mutation (SNP) | VAF 51/210 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV99343627; called by muse, mutect2, varscan2
- DNAH1 | c.887A>G p.Q296R | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs969817976; called by muse, mutect2, varscan2
- DNAH8 | c.10529G>A p.R3510Q | Missense Mutation (SNP) | VAF 8/242 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as rs1363255994; called by muse, mutect2
- DOC2A | c.191dup p.A65Cfs*10 | Frame Shift Ins (INS) | VAF 61/188 reads (32%) | catalogued as rs753153258; called by mutect2, varscan2
- DOCK3 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs553040677; called by muse, mutect2, varscan2
- DOCK7 | c.2051A>G p.Q684R | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV52003374; called by muse, mutect2, varscan2
- DOK3 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 156/408 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs767433211, COSV57251970; called by muse, mutect2, varscan2
- DQX1 | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 61/213 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs967060523; called by muse, mutect2, varscan2
- DSEL | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1373718242; called by muse, mutect2, varscan2
- E2F7 | c.2186dup p.T730Yfs*74 | Frame Shift Ins (INS) | VAF 62/196 reads (32%) | catalogued as rs36042830; called by mutect2, varscan2
- EAF2 | c.334del p.T112Qfs*30 | Frame Shift Del (DEL) | VAF 32/144 reads (22%) | catalogued as rs746509911; called by mutect2, varscan2
- ECSIT | c.97-2A>G p.X33_splice | Splice Site (SNP) | VAF 25/58 reads (43%) | catalogued as rs748751729; called by muse, mutect2, varscan2
- EGFLAM | c.2825A>G p.D942G (on ENST00000354891 / NM_001205301.2; = p.D934G on NM_152403.4) | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs377637913; called by muse, mutect2, varscan2
- EGR1 | c.1000dup p.H334Pfs*13 | Frame Shift Ins (INS) | VAF 133/404 reads (33%) | catalogued as rs746692720; called by mutect2, varscan2
- EIF4G1 | c.2080C>T p.R694C (on ENST00000346169 / NM_198241.3; = p.R498C on NM_004953.5) | Missense Mutation (SNP) | VAF 92/223 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.795); catalogued as COSV59991359; called by muse, mutect2, varscan2
- ELAVL2 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 80/262 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.081); catalogued as rs1162278674; called by muse, mutect2, varscan2
- ELMOD2 | c.135_136del p.H45Qfs*12 | Frame Shift Del (DEL) | VAF 25/129 reads (19%) | catalogued as rs1302875877; called by pindel, varscan2
- EPHB3 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 125/417 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.618); catalogued as rs759178144; called by muse, mutect2, varscan2
- FAM135A | c.2996del p.N999Ifs*5 (on ENST00000370479 / NM_001351599.1; = p.N786Ifs*5 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | catalogued as rs780725577; called by mutect2, varscan2
- FAM168B | c.115_117del p.P39del | In Frame Del (DEL) | VAF 56/205 reads (27%) | catalogued as rs769074652; called by mutect2, pindel, varscan2
- FAM171A1 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 65/225 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs757735986, COSV65317917; called by muse, mutect2, varscan2
- FAM222A | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 35/342 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV62723230; called by muse, mutect2, varscan2
- FAM47A | c.1673C>A p.P558Q | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); catalogued as rs745403635, COSV60495820; called by muse, mutect2, varscan2
- FAT1 | c.683G>A p.G228D | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV104437720, COSV71675640; called by muse, mutect2, varscan2
- FAT2 | c.1169T>C p.F390S | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as rs544578736; called by muse, mutect2, varscan2
- FAT4 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 67/237 reads (28%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.992); catalogued as COSV101272493; called by muse, mutect2, varscan2
- FBN3 | c.3316G>A p.A1106T | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as rs755591413, COSV54476124; called by muse, mutect2, varscan2
- FBXO2 | c.119C>A p.A40E | Missense Mutation (SNP) | VAF 27/718 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs953184967, COSV52354119; called by muse, mutect2
- FBXO27 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.957); catalogued as rs764710611, COSV53072525; called by muse, mutect2, varscan2
- FGFR4 | c.1814C>T p.S605F | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1241270509; called by muse, mutect2, varscan2
- FHOD1 | c.1996C>T p.R666* | Nonsense Mutation (SNP) | VAF 40/124 reads (32%) | catalogued as rs1404674367; called by muse, mutect2, varscan2
- FIBCD1 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.305); catalogued as rs897004086, COSV53393142; called by muse, mutect2
- FOXN3 | c.287dup p.S97Ifs*6 | Frame Shift Ins (INS) | VAF 23/93 reads (25%) | catalogued as rs760347049; called by mutect2, varscan2
- FOXO4 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1409892731; called by muse, mutect2, varscan2
- FXR2 | c.1619dup p.A541Sfs*14 | Frame Shift Ins (INS) | VAF 38/118 reads (32%) | catalogued as rs753982098; called by mutect2, varscan2
- GAB1 | c.50dup p.E18Gfs*34 | Frame Shift Ins (INS) | VAF 32/190 reads (17%) | catalogued as rs755581817; called by mutect2, varscan2
- GAL3ST3 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as rs1219605821; called by muse, varscan2
- GCM1 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 87/287 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99452351; called by muse, mutect2, varscan2
- GDPD2 | c.1250C>T p.T417M | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.606); catalogued as rs371744549, COSV65532799; called by muse, mutect2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 26/110 reads (24%) | catalogued as rs749150409; called by mutect2, varscan2
- GPBP1 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs1185447256; called by muse, mutect2, varscan2
- GPC4 | c.1017G>T p.Q339H | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV63697730; called by muse, mutect2, varscan2
- GPC6 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1229285968; called by muse, mutect2, varscan2
- GRIN2C | c.2350G>A p.G784R | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866984765, COSV53114449; called by muse, mutect2
- GRM7 | c.2471C>T p.T824M | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs760785925, COSV100735969, COSV63169543; called by muse, mutect2, varscan2
- GSTM2 | c.111C>T p.D37= | Splice Region (SNP) | VAF 73/276 reads (26%) | catalogued as rs1270397771; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 28/93 reads (30%) | catalogued as COSV54945907; called by mutect2, varscan2
- H3C2 | c.405_406del p.R135Sfs*12 | Frame Shift Del (DEL) | VAF 88/261 reads (34%) | catalogued as rs758780418; called by pindel, varscan2
- HCFC2 | c.926dup p.N309Kfs*34 | Frame Shift Ins (INS) | VAF 36/92 reads (39%) | catalogued as rs776023139; called by mutect2, varscan2
- HDAC7 | c.103G>A p.A35T (on ENST00000427332; = p.A74T on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/323 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs758015686; called by muse, mutect2, varscan2
- HEATR5B | c.5731G>A p.V1911I | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1459998004; called by muse, mutect2, varscan2
- HHIPL1 | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs368711613; called by muse, mutect2, varscan2
- HLA-DPB1 | c.577del p.Q193Sfs*35 | Frame Shift Del (DEL) | VAF 59/242 reads (24%) | catalogued as rs780393867; called by mutect2, pindel, varscan2
- HNF4G | c.38C>T p.A13V (on ENST00000354370 / NM_001330561.2; = p.A60V on NM_004133.5) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as COSV62967355; called by muse, mutect2, varscan2
- HOXC13 | c.336del p.T113Pfs*26 | Frame Shift Del (DEL) | VAF 55/189 reads (29%) | catalogued as rs760974507; called by mutect2, pindel, varscan2
- HOXD10 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 215/503 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as rs939576278, COSV50890721; called by muse, mutect2, varscan2
- HSPB1 | c.127T>C p.S43P | Missense Mutation (SNP) | VAF 117/570 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1346600366; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INTS10 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.838); catalogued as rs891375593, COSV67604967; called by muse, mutect2, varscan2
- IRAG1 | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs368347900; called by muse, mutect2, varscan2
- IRX1 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 110/385 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57359031; called by muse, mutect2, varscan2
- JAKMIP1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 40/434 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs1390746072; called by muse, mutect2
- JMJD4 | c.693-5C>T | Splice Region (SNP) | VAF 139/388 reads (36%) | catalogued as rs367922496; called by muse, mutect2, varscan2
- KCNAB1 | c.1156C>A p.L386I (on ENST00000490337 / NM_172160.3; = p.L375I on NM_003471.3) | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.173); catalogued as COSV56748434; called by muse, mutect2, varscan2
- KCND1 | c.1466C>T p.T489M | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs369458485; called by muse, mutect2
- KCNJ15 | c.37del p.L13Wfs*2 | Frame Shift Del (DEL) | VAF 54/144 reads (38%) | catalogued as COSV100154199; called by mutect2, pindel, varscan2
- KCNT2 | c.3032G>A p.R1011Q | Missense Mutation (SNP) | VAF 90/241 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1388663440, COSV54074433; called by muse, mutect2, varscan2
- KDF1 | c.429del p.S144Afs*104 | Frame Shift Del (DEL) | VAF 42/129 reads (33%) | catalogued as COSV57671558; called by mutect2, pindel, varscan2
- KIAA2012 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 62/268 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs554179441, COSV55576291; called by muse, varscan2
- KIF7 | c.3212G>A p.R1071Q | Missense Mutation (SNP) | VAF 169/583 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs768917109; called by muse, mutect2, varscan2
- KIFAP3 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1348714676, COSV63031739; called by muse, mutect2, varscan2
- KLHDC3 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55063440; called by muse, mutect2, varscan2
- KRT4 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 146/500 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.904); catalogued as rs747434033; called by muse, mutect2, varscan2
- LAMA1 | c.2677G>A p.A893T | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377014414; called by muse, mutect2, varscan2
- LCE2B | c.245A>G p.H82R | Missense Mutation (SNP) | VAF 105/346 reads (30%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.095); catalogued as COSV100909277; called by muse, mutect2, varscan2
- LDLRAD4 | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 104/324 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs755173136; called by muse, mutect2, varscan2
- LENG8 | c.938C>T p.T313M | Missense Mutation (SNP) | VAF 208/552 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs750220608, COSV58727365, COSV58727682; called by muse, mutect2, varscan2
- LRP4 | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 10/307 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1249967861; called by muse, mutect2
- LRRC66 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 100/275 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV58631933; called by muse, mutect2, varscan2
- LTN1 | c.4897C>T p.R1633* | Nonsense Mutation (SNP) | VAF 29/100 reads (29%) | catalogued as rs768520074, COSV63733535; called by muse, mutect2, varscan2
- LTO1 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 16/372 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.65); catalogued as rs1165449107, COSV57121833; called by muse, mutect2
- MACF1 | c.5611C>A p.L1871I | Missense Mutation (SNP) | VAF 43/181 reads (24%) | catalogued as COSV57110163; called by muse, mutect2, varscan2
- MAN2C1 | c.3044G>A p.R1015Q | Missense Mutation (SNP) | VAF 105/303 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs773801306, COSV99145568; called by muse, mutect2, varscan2
- MAP3K8 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1170356333; called by muse, mutect2
- MAP7D1 | c.245dup p.Q83Afs*8 | Frame Shift Ins (INS) | VAF 14/46 reads (30%) | catalogued as rs765962881; called by mutect2, varscan2
- MED22 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV59298472; called by muse, mutect2, varscan2
- MEX3A | c.201del p.G68Afs*59 | Frame Shift Del (DEL) | VAF 30/96 reads (31%) | catalogued as COSV64142604; called by pindel, varscan2
- MFSD12 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 67/216 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.329); catalogued as rs1329439093; called by muse, mutect2, varscan2
- MIS18BP1 | c.471del p.K157Nfs*24 | Frame Shift Del (DEL) | VAF 21/35 reads (60%) | catalogued as rs546807245; called by mutect2, varscan2
- MKI67 | c.698del p.N233Mfs*12 | Frame Shift Del (DEL) | VAF 48/162 reads (30%) | catalogued as rs749903408; called by mutect2, varscan2
- MST1L | n.925G>A | Splice Region (SNP) | VAF 12/96 reads (13%) | catalogued as rs1488750183; called by mutect2, varscan2
- MT2A | c.128A>G p.K43R | Missense Mutation (SNP) | VAF 91/266 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1567338125; called by muse, mutect2, varscan2
- MTIF2 | c.1974del p.K658Nfs*4 | Frame Shift Del (DEL) | VAF 40/135 reads (30%) | catalogued as rs770359991; called by mutect2, varscan2
- MTM1 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as rs782468721, COSV60335430; called by muse, mutect2, varscan2
- MUC5B | c.14374G>A p.V4792M | Missense Mutation (SNP) | VAF 144/426 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV71592169; called by muse, mutect2, varscan2
- MYH14 | c.3442C>T p.R1148C | Missense Mutation (SNP) | VAF 85/310 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs374305829; called by muse, mutect2, varscan2
- NALCN | c.2577C>T p.N859= | Splice Region (SNP) | VAF 66/161 reads (41%) | catalogued as rs139541927; called by muse, mutect2, varscan2
- NEUROG3 | c.107C>A p.P36Q | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV54342669; called by muse, mutect2, varscan2
- NGDN | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs763908852, COSV68142812; called by muse, mutect2, varscan2
- NOB1 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 87/281 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs768728190, COSV99263827; called by muse, mutect2, varscan2
- NOD2 | c.1583del p.P528Qfs*235 | Frame Shift Del (DEL) | VAF 39/145 reads (27%) | catalogued as rs754073471; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NOLC1 | c.840del p.K280Nfs*3 | Frame Shift Del (DEL) | VAF 58/164 reads (35%) | catalogued as rs759637346; called by mutect2, varscan2
- NOS3 | c.1319dup p.C441Lfs*57 | Frame Shift Ins (INS) | VAF 80/369 reads (22%) | catalogued as rs749517498; called by mutect2, varscan2
- NOTCH3 | c.125dup p.C43Lfs*32 | Frame Shift Ins (INS) | VAF 37/130 reads (28%) | catalogued as rs749829137; called by mutect2, varscan2
- NOVA2 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 114/262 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs989602487; called by muse, mutect2, varscan2
- NPAS3 | c.331del p.D111Tfs*17 (on ENST00000356141 / NM_001164749.2; = p.D81Tfs*17 on NM_022123.3) | Frame Shift Del (DEL) | VAF 57/198 reads (29%) | catalogued as COSV58076957; called by mutect2, varscan2
- NPAT | c.2786-3del | Splice Region (DEL) | VAF 54/206 reads (26%) | catalogued as rs35747263; called by mutect2, varscan2
- NPBWR1 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 104/309 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.267); catalogued as COSV100488338; called by muse, varscan2
- NUDT11 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1557326662; called by muse, mutect2, varscan2
- OR2A25 | c.719G>A p.C240Y | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772583203; called by muse, mutect2, varscan2
- OR4E2 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs768351804; called by muse, mutect2, varscan2
- OR4N2 | chr14:19828372 del A | Frame Shift Del (DEL) | VAF 19/84 reads (23%) | catalogued as rs1233785490; called by mutect2, pindel, varscan2
- OR4P4 | c.315del p.F105Lfs*4 | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | catalogued as rs748398423; called by mutect2, varscan2
- PARP9 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as rs772861803, COSV64450043; called by muse, mutect2, varscan2
- PASD1 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 104/366 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370064836, COSV64854833; called by muse, mutect2, varscan2
- PCDH7 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 135/351 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100688692; called by muse, mutect2, varscan2
- PCDHB7 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 324/936 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as rs782029168, COSV50754198; called by muse, mutect2, varscan2
- PDE4A | c.367dup p.L123Pfs*33 | Frame Shift Ins (INS) | VAF 111/382 reads (29%) | catalogued as rs1555731362; called by mutect2, pindel, varscan2
- PDE4D | c.601C>A p.L201I (on ENST00000340635 / NM_001104631.2; = p.L65I on NM_006203.4) | Missense Mutation (SNP) | VAF 120/435 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.344); catalogued as rs762270122; called by muse, mutect2, varscan2
- PER2 | c.2227C>T p.Q743* | Nonsense Mutation (SNP) | VAF 108/366 reads (30%) | catalogued as COSV99612617; called by muse, mutect2, varscan2
- PGAP2 | c.584_586del p.F195del (on ENST00000463452 / NM_001346398.2; = p.F256del on NM_014489.4) | In Frame Del (DEL) | VAF 58/272 reads (21%) | catalogued as rs777098385; called by pindel, varscan2
- PHGR1 | c.109del p.H37Tfs*71 | Frame Shift Del (DEL) | VAF 38/154 reads (25%) | catalogued as rs1264440278; called by pindel, varscan2
- PIK3CG | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 112/340 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as rs778022267, COSV63248617; called by muse, mutect2, varscan2
- PIP4P1 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 95/301 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs1347366025; called by muse, mutect2, varscan2
- PKD1L2 | n.430del | Splice Region (DEL) | VAF 26/102 reads (25%) | catalogued as rs755082958; called by mutect2, pindel, varscan2
- PKD2 | c.2587G>A p.V863M | Missense Mutation (SNP) | VAF 154/427 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs766821096, COSV52939396, COSV99417949; called by muse, mutect2, varscan2
- PLEKHG2 | c.3964del p.Q1322Sfs*37 | Frame Shift Del (DEL) | VAF 16/63 reads (25%) | catalogued as rs551236586; called by mutect2, pindel, varscan2
- PPP1R27 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs369174976; called by muse, mutect2, varscan2
- PPP1R3A | c.1428del p.N476Kfs*4 | Frame Shift Del (DEL) | VAF 25/129 reads (19%) | catalogued as rs1056475720, COSV52881818; called by mutect2, pindel, varscan2
- PRELID1 | c.513C>T p.G171= | Splice Region (SNP) | VAF 97/296 reads (33%) | catalogued as rs374141318; called by muse, mutect2, varscan2
- PRKCH | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs746996721, COSV60646823, COSV60649045; called by muse, mutect2
- PRR36 | c.191del p.G64Afs*146 | Frame Shift Del (DEL) | VAF 51/195 reads (26%) | catalogued as rs1327235205; called by mutect2, pindel, varscan2
- PSG2 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as rs746771821, COSV61546440; called by muse, mutect2, varscan2
- RAP1B | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1192019330, COSV51667078; called by muse, mutect2, varscan2
- RARB | c.923T>C p.L308P (on ENST00000383772 / NM_001290216.2; = p.L301P on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 128/364 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs1324006465; called by muse, mutect2, varscan2
- RASSF1 | c.880del p.E294Rfs*2 (on ENST00000357043 / NM_170714.2; = p.E290Rfs*2 on NM_007182.5) | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs776701982; called by mutect2, pindel, varscan2
- RBM10 | c.2326C>T p.R776W | Missense Mutation (SNP) | VAF 16/480 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1556782020, COSV61307580; called by muse, mutect2
- RBP4 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 200/579 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs139534453; called by muse, mutect2, varscan2
- RHBDL1 | c.1307dup p.P437Tfs*68 (on ENST00000219551 / NM_001318733.2; = p.P372Tfs*68 on NM_001278720.2) | Frame Shift Ins (INS) | VAF 15/68 reads (22%) | catalogued as rs1391030139; called by mutect2, pindel, varscan2
- RIC1 | c.145-1G>A p.X49_splice | Splice Site (SNP) | VAF 12/59 reads (20%) | catalogued as rs1305046325; called by muse, varscan2
- RING1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 53/512 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV100761797, COSV63002861; called by muse, mutect2
- RREB1 | c.3916G>A p.A1306T | Missense Mutation (SNP) | VAF 83/236 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1255600847; called by muse, mutect2, varscan2
- RYR3 | c.5148dup p.S1717Vfs*23 | Frame Shift Ins (INS) | VAF 69/250 reads (28%) | catalogued as rs760871679; called by mutect2, pindel, varscan2
- SARS1 | c.1537G>A p.D513N | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.067); catalogued as rs774591894; called by muse, mutect2, varscan2
- SBF1 | c.3701C>T p.A1234V | Missense Mutation (SNP) | VAF 96/250 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.371); catalogued as rs763261910; called by muse, mutect2, varscan2
- SCARF2 | c.1096G>A p.G366S | Missense Mutation (SNP) | VAF 141/410 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754340473; called by muse, mutect2, varscan2
- SCN5A | c.5069A>G p.D1690G (on ENST00000333535 / NM_198056.3; = p.D1689G on NM_000335.5) | Missense Mutation (SNP) | VAF 197/517 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD100799; called by muse, mutect2, varscan2
- SCRIB | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 95/306 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776303551; called by muse, mutect2, varscan2
- SEL1L2 | c.971A>G p.Y324C | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53156723; called by muse, mutect2, varscan2
- SETD1B | c.22dup p.H8Pfs*30 | Frame Shift Ins (INS) | VAF 14/52 reads (27%) | catalogued as rs777278685; called by mutect2, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | catalogued as rs1260834379; called by mutect2, varscan2
- SH3TC1 | c.3145G>A p.A1049T | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs147442685, COSV55283589; called by muse, mutect2
- SHROOM1 | c.38del p.P13Rfs*46 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as COSV60580848; called by mutect2, varscan2
- SIPA1L1 | c.172del p.R58Efs*8 | Frame Shift Del (DEL) | VAF 55/189 reads (29%) | catalogued as rs1567251966; called by mutect2, pindel, varscan2
- SLC25A24 | c.570del p.K190Nfs*29 | Frame Shift Del (DEL) | VAF 68/234 reads (29%) | catalogued as rs763273320; called by mutect2, varscan2
- SLC25A41 | c.100del p.Q34Nfs*44 | Frame Shift Del (DEL) | VAF 26/83 reads (31%) | catalogued as rs745556777; called by mutect2, pindel
- SLC4A2 | c.1909C>T p.R637* | Nonsense Mutation (SNP) | VAF 82/392 reads (21%) | catalogued as rs916701727; called by muse, mutect2, varscan2
- SLC9A7 | c.1222C>T p.R408* | Nonsense Mutation (SNP) | VAF 38/215 reads (18%) | catalogued as COSV60384826; called by muse, mutect2, varscan2
- SLCO1C1 | c.710T>A p.I237N | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs755197753; called by muse, mutect2, varscan2
- SMTN | c.1605dup p.S536Qfs*2 | Frame Shift Ins (INS) | VAF 16/62 reads (26%) | catalogued as rs758895137; called by mutect2, varscan2
- SNX17 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs1340190010; called by muse, mutect2
- SOX10 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs774135262; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SP5 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs1438529009; called by muse, mutect2, varscan2
- SPATA2L | c.643dup p.R215Pfs*37 | Frame Shift Ins (INS) | VAF 58/199 reads (29%) | catalogued as rs775005823; called by mutect2, varscan2
- SPG11 | c.3619C>T p.R1207W | Missense Mutation (SNP) | VAF 112/303 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199986067, COSV55993591; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SSTR4 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs757025068, COSV54798836; called by muse, mutect2, varscan2
- STARD4 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs767010005, COSV56967331; called by muse, mutect2, varscan2
- STIM2 | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 132/335 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.04); catalogued as rs150484445; called by muse, mutect2, varscan2
- TBC1D10A | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs187717533, COSV53165021; called by muse, mutect2, varscan2
- TEPP | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); catalogued as rs200723974; called by muse, mutect2, varscan2
- TFPI | c.536-5del | Splice Region (DEL) | VAF 32/116 reads (28%) | catalogued as rs771312944; called by mutect2, pindel, varscan2
- THEG | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs139413039, COSV100700638; called by muse, mutect2, varscan2
- TICAM1 | c.1616T>C p.M539T | Missense Mutation (SNP) | VAF 127/278 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs377509189; called by muse, mutect2, varscan2
- TIGD2 | c.211A>G p.M71V | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs1379319698; called by muse, mutect2, varscan2
- TMEM150A | c.121_123del p.N41del (on ENST00000334462 / NM_001031738.3; = p.T11del on NM_153342.3) | In Frame Del (DEL) | VAF 68/203 reads (33%) | catalogued as rs750134630; called by mutect2, pindel, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 42/123 reads (34%) | catalogued as rs749773249; called by mutect2, varscan2
- TMEM69 | c.*4del | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | catalogued as rs1303076775; called by mutect2, pindel, varscan2
- TMEM94 | c.657del p.F220Sfs*31 | Frame Shift Del (DEL) | VAF 45/186 reads (24%) | catalogued as rs753764149; called by mutect2, pindel, varscan2
- TNF | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 85/245 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs770509340; called by muse, mutect2, varscan2
- TPRX1 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs926667503; called by muse, mutect2, varscan2
- TRIM3 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs775151876, COSV61983955; called by muse, mutect2
- TRIM49D1 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs757772073; called by mutect2, varscan2
- TRIM71 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 97/228 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs572598561, COSV101070368; called by muse, mutect2, varscan2
- TRIML1 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs766822406, COSV60196898; called by muse, mutect2, varscan2
- TRPM2 | c.529del p.A177Pfs*6 | Frame Shift Del (DEL) | VAF 43/173 reads (25%) | catalogued as rs762935066, COSV55967995; called by mutect2, pindel
- TRRAP | c.5156G>A p.R1719Q (on ENST00000359863 / NM_001244580.1; = p.R1701Q on NM_003496.3) | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV62839379; called by muse, mutect2, varscan2
- TSBP1 | c.670del p.S224Lfs*8 (on ENST00000617061; = p.S227Lfs*8 on NM_006781.5) | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | catalogued as COSV66660771; called by mutect2, varscan2
- TTK | c.2571del p.K857Nfs*36 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | catalogued as rs768996038, COSV57882295; called by mutect2, pindel, varscan2
- TTLL8 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 82/251 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as rs569616807; called by muse, mutect2, varscan2
- UNCX | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 127/238 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763937670; called by muse, mutect2, varscan2
- UTP20 | c.392dup p.L131Ffs*27 | Frame Shift Ins (INS) | VAF 20/78 reads (26%) | catalogued as rs761528888; called by mutect2, varscan2
- VHL | c.271T>C p.F91L | Missense Mutation (SNP) | VAF 227/683 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV56572601; called by muse, varscan2
- VMP1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs1227158919, COSV99230927; called by muse, mutect2, varscan2
- WDR87 | c.4753G>A p.E1585K | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.124); catalogued as rs1434760661; called by muse, varscan2
- XKR5 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV68398693; called by muse, mutect2
- ZFP37 | c.482del p.N161Ifs*24 | Frame Shift Del (DEL) | VAF 26/86 reads (30%) | catalogued as rs563751025; called by mutect2, varscan2
- ZNF276 | c.1349G>A p.G450D (on ENST00000443381 / NM_001113525.2; = p.G375D on NM_152287.4) | Missense Mutation (SNP) | VAF 107/314 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57066749; called by muse, mutect2, varscan2
- ZNF423 | c.3421G>A p.E1141K (on ENST00000563137 / NM_001379286.1; = p.E1133K on NM_015069.4) | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.094); catalogued as rs1000393255, COSV99283075; called by muse, mutect2, varscan2
- ZNF541 | c.692del p.P231Rfs*49 | Frame Shift Del (DEL) | VAF 37/140 reads (26%) | catalogued as rs780386192; called by mutect2, pindel, varscan2
- ZNF609 | c.2087C>A p.P696H | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV58583160; called by muse, mutect2, varscan2
- ZNF697 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV70284346; called by muse, mutect2, varscan2
- ZNF814 | c.1276C>T p.H426Y | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761897245; called by muse, mutect2, varscan2
- ZNF84 | c.1835C>T p.S612L | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs1020095605; called by muse, mutect2, varscan2
- ZNRF3 | c.2483G>A p.R828H (on ENST00000544604 / NM_001206998.2; = p.R728H on NM_032173.3) | Missense Mutation (SNP) | VAF 98/273 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs557631529; called by muse, mutect2, varscan2
- ZSWIM8 | c.5085del p.Y1696Tfs*17 (on ENST00000605216 / NM_001242487.2; = p.Y1701Tfs*17 on NM_015037.3) | Frame Shift Del (DEL) | VAF 27/141 reads (19%) | catalogued as rs769663113; called by mutect2, varscan2
- ZZEF1 | c.5786G>A p.R1929H | Missense Mutation (SNP) | VAF 142/613 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs142520166; called by muse, mutect2, varscan2
- AC026316.4 | c.478dup p.S160Ffs*41 | Frame Shift Ins (INS) | VAF 38/153 reads (25%) | called by mutect2, pindel, varscan2
- ACAP2 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- ACTR10 | c.153T>C p.P51= | Splice Region (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- ACTRT2 | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 105/411 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- ADAL | c.651del p.E218Kfs*33 | Frame Shift Del (DEL) | VAF 32/98 reads (33%) | called by mutect2, varscan2
- ADAM8 | c.1783_1785del p.K595del | In Frame Del (DEL) | VAF 19/68 reads (28%) | called by mutect2, pindel, varscan2
- ADAMTS5 | c.2789G>C p.C930S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ADCY8 | c.374del p.G125Afs*60 | Frame Shift Del (DEL) | VAF 30/102 reads (29%) | called by mutect2, pindel, varscan2
- ADGRG4 | c.7250del p.N2417Mfs*47 | Frame Shift Del (DEL) | VAF 33/145 reads (23%) | called by mutect2, pindel, varscan2
- AFAP1 | c.1139G>A p.R380K | Missense Mutation (SNP) | VAF 130/471 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- AFF2 | c.345dup p.P116Sfs*14 | Frame Shift Ins (INS) | VAF 51/168 reads (30%) | called by mutect2, pindel, varscan2
- ALG13 | c.597del p.T200Pfs*18 | Frame Shift Del (DEL) | VAF 76/270 reads (28%) | called by mutect2, pindel, varscan2
- ALMS1 | c.5912_5913del p.S1971Yfs*15 | Frame Shift Del (DEL) | VAF 20/162 reads (12%) | called by mutect2, pindel, varscan2
- ANK1 | c.3079_3080del p.S1027Lfs*89 | Frame Shift Del (DEL) | VAF 120/425 reads (28%) | called by pindel, varscan2
- ANKRD11 | c.7481del p.P2494Lfs*8 | Frame Shift Del (DEL) | VAF 63/229 reads (28%) | called by mutect2, pindel, varscan2
- ARHGAP10 | c.1142T>C p.I381T | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP42 | c.1376del p.N459Tfs*10 | Frame Shift Del (DEL) | VAF 25/106 reads (24%) | called by mutect2, pindel, varscan2
- ARID1A | c.5688del p.P1898Hfs*25 | Frame Shift Del (DEL) | VAF 71/222 reads (32%) | called by mutect2, pindel, varscan2
- ASCL4 | c.109del p.L37Sfs*53 | Frame Shift Del (DEL) | VAF 130/454 reads (29%) | called by mutect2, varscan2
- ASH1L | c.8143C>T p.R2715W (on ENST00000368346 / NM_001366177.2; = p.R2710W on NM_018489.3) | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP6AP2 | c.955G>A p.A319T (on ENST00000378438; = p.A320T on NM_005765.3) | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- AVPR2 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 272/784 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- BDP1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 137/375 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- BDP1 | c.6580G>A p.E2194K | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- BHLHA9 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.312); called by muse, mutect2
- BMPR1A | c.9G>C p.Q3H | Missense Mutation (SNP) | VAF 74/216 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- BTN2A2 | c.73A>C p.S25R | Missense Mutation (SNP) | VAF 20/482 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2
- C2CD3 | c.1520G>T p.R507I | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- C2orf81 | c.799del p.L267Sfs*67 | Frame Shift Del (DEL) | VAF 22/81 reads (27%) | called by mutect2, pindel, varscan2
- CACNA1C | c.4825G>A p.G1609S | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- CACNA1G | c.5356C>T p.R1786W | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- CACNA1I | c.6567del p.G2190Afs*82 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | called by mutect2, varscan2
- CCDC102A | c.1031G>T p.R344M | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC80 | c.2711C>T p.A904V | Missense Mutation (SNP) | VAF 84/321 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- CCND1 | c.866_871dup p.V290_R291insHV | In Frame Ins (INS) | VAF 25/81 reads (31%) | called by mutect2, pindel, varscan2
- CCT3 | c.591del p.K197Nfs*23 | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | called by mutect2, pindel
- CDIN1 | c.278A>G p.D93G | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CDK18 | c.451C>T p.P151S (on ENST00000506784 / NM_212503.3; = p.P121S on NM_002596.4) | Missense Mutation (SNP) | VAF 88/285 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CEACAM5 | c.62C>T p.T21I | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- CEACAM5 | c.1685C>T p.T562I | Missense Mutation (SNP) | VAF 23/403 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.167); called by muse, mutect2
- CFAP46 | c.2869G>C p.A957P | Missense Mutation (SNP) | VAF 97/317 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHD6 | c.2134C>T p.R712C | Missense Mutation (SNP) | VAF 29/652 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CKB | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 38/133 reads (29%) | called by muse, mutect2, varscan2
- CLIC3 | c.565C>T p.H189Y | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLIP2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 123/739 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CNOT4 | c.68T>C p.I23T | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- CNTNAP2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 72/291 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- CNTRL | c.2822A>G p.D941G | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- COL6A3 | c.7319C>A p.P2440Q | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A3 | c.4091T>C p.V1364A | Missense Mutation (SNP) | VAF 150/438 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CTNNA1 | c.1545A>G p.S515= | Splice Region (SNP) | VAF 35/89 reads (39%) | called by muse, mutect2, varscan2
- CTNS | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 191/668 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by mutect2, varscan2
- CTTN | c.574T>A p.S192T | Missense Mutation (SNP) | VAF 71/225 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CUBN | c.4192G>A p.A1398T | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2
- CUX1 | c.1123C>T p.Q375* (on ENST00000292535 / NM_181552.4; = p.Q386* on NM_001913.5) | Nonsense Mutation (SNP) | VAF 87/418 reads (21%) | called by muse, mutect2, varscan2
- CXCL16 | c.410del p.P137Lfs*19 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | called by mutect2, pindel
- CYP2W1 | c.823del p.X275_splice | Splice Site (DEL) | VAF 26/69 reads (38%) | called by mutect2, pindel
- CYSLTR1 | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DDX49 | c.1331A>C p.K444T | Missense Mutation (SNP) | VAF 132/372 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DHX16 | c.921+2T>C p.X307_splice | Splice Site (SNP) | VAF 54/156 reads (35%) | called by muse, mutect2
- DLX1 | c.584A>G p.E195G | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, varscan2
- DMXL1 | c.8202A>C p.R2734S | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DNAH10 | c.10103A>G p.Q3368R (on ENST00000409039; = p.Q3307R on NM_207437.3) | Missense Mutation (SNP) | VAF 87/256 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- DNAH7 | c.472_475del p.E158Kfs*4 | Frame Shift Del (DEL) | VAF 45/125 reads (36%) | called by mutect2, pindel, varscan2
- DTX4 | c.1852_1854del p.K618del | In Frame Del (DEL) | VAF 56/138 reads (41%) | called by mutect2, pindel
- DYRK1A | c.452del p.N151Tfs*14 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | called by mutect2, pindel, varscan2
- DYRK2 | c.529A>G p.S177G (on ENST00000344096 / NM_006482.3; = p.S104G on NM_003583.4) | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EEF1A2 | c.714del p.T239Rfs*40 | Frame Shift Del (DEL) | VAF 75/297 reads (25%) | called by mutect2, pindel, varscan2
- EEFSEC | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 166/597 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- EFCC1 | c.413C>A p.P138Q | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- EGF | c.2053G>A p.G685S | Missense Mutation (SNP) | VAF 122/361 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EMB | c.379T>C p.Y127H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- EML5 | c.1718A>G p.H573R | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- EPG5 | c.6267del p.S2090Lfs*27 | Frame Shift Del (DEL) | VAF 41/125 reads (33%) | called by mutect2, pindel, varscan2
- ERV3-1 | c.583A>G p.S195G | Missense Mutation (SNP) | VAF 52/334 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESCO1 | c.1872G>A p.M624I | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FAM131A | c.344C>T p.A115V (on ENST00000310585; = p.A146V on NM_144635.5) | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FAM189A2 | c.1266del p.R423Gfs*83 | Frame Shift Del (DEL) | VAF 218/746 reads (29%) | called by mutect2, pindel, varscan2
- FAM50A | c.857A>G p.D286G | Missense Mutation (SNP) | VAF 20/347 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.708); called by muse, mutect2
- FAM83E | c.1255G>T p.G419W | Missense Mutation (SNP) | VAF 74/132 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- FAT3 | c.7225del p.R2409Gfs*5 | Frame Shift Del (DEL) | VAF 27/95 reads (28%) | called by mutect2, varscan2
- FBLN2 | c.305C>A p.P102Q | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.096); called by muse, mutect2
- FBXO3 | c.502C>T p.H168Y | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.091); called by muse, mutect2
- FBXO46 | c.542A>G p.Q181R | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- FER1L5 | c.3023T>C p.I1008T (on ENST00000623019; = p.I1015T on NM_001293083.2) | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- FNIP1 | c.2624C>T p.T875I | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- FZD10 | c.980G>T p.W327L | Missense Mutation (SNP) | VAF 15/353 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GAPDHS | c.16A>C p.I6L | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GAS2L1 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.851); called by muse, varscan2
- GCLC | c.1590del p.G531Vfs*6 (on ENST00000643939; = p.G529Vfs*6 on NM_001498.4) | Frame Shift Del (DEL) | VAF 97/373 reads (26%) | called by mutect2, pindel, varscan2
- GDF6 | c.1358G>A p.G453D | Missense Mutation (SNP) | VAF 124/363 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLIS3 | c.1451C>T p.T484I | Missense Mutation (SNP) | VAF 77/359 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIA4 | c.2023G>A p.G675R | Missense Mutation (SNP) | VAF 9/227 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRK6 | c.90G>A p.W30* | Nonsense Mutation (SNP) | VAF 73/275 reads (27%) | called by muse, mutect2, varscan2
- GTPBP6 | c.1456G>T p.E486* | Nonsense Mutation (SNP) | VAF 111/295 reads (38%) | called by muse, mutect2, varscan2
- HACE1 | c.1378del p.Y460Tfs*12 | Frame Shift Del (DEL) | VAF 15/157 reads (10%) | called by mutect2, pindel
- HEATR1 | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.221); called by muse, mutect2
- HECTD4 | c.10448C>T p.A3483V | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HMG20A | c.605A>G p.H202R | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- HMGN5 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HS3ST6 | c.637C>A p.L213M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- HTR3B | c.1193C>T p.T398I | Missense Mutation (SNP) | VAF 141/461 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- HUWE1 | c.1169del p.L390Yfs*19 | Frame Shift Del (DEL) | VAF 40/156 reads (26%) | called by pindel, varscan2
- HYKK | c.701T>C p.I234T | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, varscan2
- IGFALS | c.1538T>C p.L513P | Missense Mutation (SNP) | VAF 22/520 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ILRUN | c.292del p.T98Hfs*29 (on ENST00000374023 / NM_024294.4; = p.T98Hfs*12 on NM_022758.6) | Frame Shift Del (DEL) | VAF 31/102 reads (30%) | called by mutect2, pindel, varscan2
- IRF2BP2 | c.1657dup p.E553Gfs*49 | Frame Shift Ins (INS) | VAF 83/291 reads (29%) | called by mutect2, pindel, varscan2
- ITFG1 | c.1663dup p.W555Lfs*11 | Frame Shift Ins (INS) | VAF 19/74 reads (26%) | called by mutect2, pindel
- ITSN1 | c.299del p.P100Lfs*3 | Frame Shift Del (DEL) | VAF 16/107 reads (15%) | called by mutect2, pindel, varscan2
- KCNH6 | c.137A>G p.D46G | Missense Mutation (SNP) | VAF 148/438 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNMA1 | c.3343-4C>A | Splice Region (SNP) | VAF 121/420 reads (29%) | called by muse, mutect2, varscan2
- KCNMB3 | c.729dup p.Y244Ifs*2 | Frame Shift Ins (INS) | VAF 16/94 reads (17%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.7317+2T>C p.X2439_splice | Splice Site (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- KMT2B | c.3412C>T p.R1138* | Nonsense Mutation (SNP) | VAF 133/433 reads (31%) | called by muse, mutect2, varscan2
- KMT2D | c.5821_5822insG p.M1941Sfs*16 | Frame Shift Ins (INS) | VAF 32/96 reads (33%) | called by mutect2, varscan2
- KMT2D | c.5819dup p.M1941Nfs*16 | Frame Shift Ins (INS) | VAF 26/116 reads (22%) | called by mutect2*, pindel, varscan2*
- KNDC1 | c.3793A>G p.S1265G | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- KRTAP4-2 | c.70A>G p.S24G | Missense Mutation (SNP) | VAF 124/354 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LAG3 | c.917A>G p.D306G | Missense Mutation (SNP) | VAF 160/495 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- LCE1C | c.92del p.P31Qfs*47 | Frame Shift Del (DEL) | VAF 87/337 reads (26%) | called by mutect2, pindel, varscan2
- LGI4 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2
- LHCGR | c.1792C>G p.L598V | Missense Mutation (SNP) | VAF 127/354 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LIG4 | c.358G>T p.G120* | Nonsense Mutation (SNP) | VAF 29/130 reads (22%) | called by muse, mutect2, varscan2
- LMNA | c.1165C>A p.L389M | Missense Mutation (SNP) | VAF 96/323 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- LPIN1 | c.1564del p.L522Sfs*21 | Frame Shift Del (DEL) | VAF 94/368 reads (26%) | called by mutect2, pindel, varscan2
- MACROH2A2 | c.438del p.K147Rfs*53 | Frame Shift Del (DEL) | VAF 40/179 reads (22%) | called by mutect2, pindel
- MAPK8IP3 | c.1894G>A p.D632N | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.116); called by muse, mutect2
- MAVS | c.109A>G p.R37G | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MED10 | c.388del p.E130Rfs*14 | Frame Shift Del (DEL) | VAF 60/243 reads (25%) | called by mutect2, pindel, varscan2
- MED17 | c.804A>G p.I268M | Missense Mutation (SNP) | VAF 88/287 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MEIS3 | c.555C>G p.D185E | Missense Mutation (SNP) | VAF 116/345 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- MFAP3 | c.976del p.S326Vfs*18 | Frame Shift Del (DEL) | VAF 68/253 reads (27%) | called by mutect2, pindel, varscan2
- MFSD2A | c.584C>T p.A195V (on ENST00000372809 / NM_001136493.3; = p.A182V on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- MMP15 | c.705del p.F235Lfs*85 | Frame Shift Del (DEL) | VAF 84/251 reads (33%) | called by mutect2, pindel, varscan2
- MMRN2 | c.137A>C p.E46A | Missense Mutation (SNP) | VAF 152/437 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- MRC1 | c.4199del p.L1400* | Frame Shift Del (DEL) | VAF 180/801 reads (22%) | called by mutect2, pindel, varscan2
- MRNIP | c.74dup p.S26Efs*21 | Frame Shift Ins (INS) | VAF 51/188 reads (27%) | called by mutect2, pindel, varscan2
- MROH5 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 102/281 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MUC12 | c.5542A>T p.T1848S (on ENST00000379442; = p.T1705S on NM_001164462.1) | Missense Mutation (SNP) | VAF 172/868 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- MUC5B | c.6152T>C p.V2051A | Missense Mutation (SNP) | VAF 159/468 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MUC6 | c.1790G>T p.R597M | Missense Mutation (SNP) | VAF 29/286 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- MVK | c.347A>T p.Y116F | Missense Mutation (SNP) | VAF 309/769 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MXRA5 | c.6989T>C p.V2330A | Missense Mutation (SNP) | VAF 106/328 reads (32%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- MYF6 | c.264dup p.S89Ifs*5 | Frame Shift Ins (INS) | VAF 168/516 reads (33%) | called by mutect2, pindel, varscan2
- MYH11 | c.1061T>C p.L354P | Missense Mutation (SNP) | VAF 132/485 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MYH14 | c.5060A>C p.E1687A | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- MYO16 | c.1424_1426del p.S475del | In Frame Del (DEL) | VAF 43/179 reads (24%) | called by mutect2, pindel, varscan2
- MYO1C | c.2966del p.K989Rfs*11 (on ENST00000648651 / NM_001080779.2; = p.K954Rfs*11 on NM_033375.5) | Frame Shift Del (DEL) | VAF 91/311 reads (29%) | called by mutect2, pindel, varscan2
- MYO3B | c.324G>A p.L108= | Splice Region (SNP) | VAF 96/246 reads (39%) | called by muse, mutect2, varscan2
- MYO5B | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 213/753 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.232); called by muse, mutect2
- NAA35 | c.1646G>T p.R549M | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- NEDD4L | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 74/244 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- NFKBIA | c.833A>G p.Q278R | Missense Mutation (SNP) | VAF 142/399 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NFXL1 | c.944A>C p.K315T | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NKX1-1 | c.802G>C p.G268R | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- NKX6-1 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.103); called by muse, varscan2
- NKX6-2 | c.170del p.P57Rfs*131 | Frame Shift Del (DEL) | VAF 23/92 reads (25%) | called by mutect2, pindel, varscan2
- NLRP8 | c.2477del p.N826Tfs*21 | Frame Shift Del (DEL) | VAF 50/182 reads (27%) | called by mutect2, pindel, varscan2
- NRG2 | c.1373C>A p.P458H | Missense Mutation (SNP) | VAF 94/329 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRP1 | c.1046C>T p.T349I | Missense Mutation (SNP) | VAF 57/202 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NT5DC1 | c.1079A>G p.Y360C | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); called by muse, varscan2
- NTM | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 81/261 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- NUP107 | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- NYAP1 | c.974dup p.P326Afs*109 | Frame Shift Ins (INS) | VAF 23/109 reads (21%) | called by mutect2, pindel, varscan2
- OBP2B | c.295A>G p.M99V | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR1A2 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OTOG | c.7305C>A p.A2435= | Splice Region (SNP) | VAF 32/99 reads (32%) | called by muse, mutect2, varscan2
- OTUD7A | c.1732A>C p.S578R (on ENST00000307050 / NM_001382637.1; = p.S571R on NM_130901.3) | Missense Mutation (SNP) | VAF 84/282 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- PAIP1 | c.1310A>G p.E437G | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PCDHA2 | c.1181C>A p.P394H | Missense Mutation (SNP) | VAF 112/349 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- PCDHGA12 | c.1990G>A p.V664M | Missense Mutation (SNP) | VAF 203/618 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- PCLO | c.6692A>C p.Y2231S | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PEX6 | c.1229A>G p.Y410C | Missense Mutation (SNP) | VAF 176/537 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PGAM5 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 59/238 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PHF20L1 | c.893del p.K298Rfs*66 | Frame Shift Del (DEL) | VAF 87/313 reads (28%) | called by mutect2, pindel, varscan2
- PHF23 | c.309dup p.A104Sfs*26 | Frame Shift Ins (INS) | VAF 101/329 reads (31%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1357_1362del p.N453_T454del (on ENST00000521381 / NM_181523.3; = p.N183_T184del on NM_181504.4) | In Frame Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- PKP2 | c.2145A>G p.P715= | Splice Region (SNP) | VAF 114/328 reads (35%) | called by muse, mutect2, varscan2
- PLEKHG6 | c.1408+7C>T | Splice Region (SNP) | VAF 65/291 reads (22%) | called by muse, mutect2, varscan2
- PLET1 | c.116A>G p.E39G | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- PLXNA2 | c.1370del p.K457Rfs*65 | Frame Shift Del (DEL) | VAF 91/360 reads (25%) | called by mutect2, pindel, varscan2
- PMPCA | c.888del p.I297Lfs*4 | Frame Shift Del (DEL) | VAF 9/77 reads (12%) | called by mutect2, pindel, varscan2
- PNKD | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 86/322 reads (27%) | called by muse, mutect2, varscan2
- PNPT1 | c.1821A>G p.V607= | Splice Region (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- POGZ | c.3548C>A p.P1183H | Missense Mutation (SNP) | VAF 63/248 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- POP1 | c.2362G>A p.D788N | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- POTEE | c.2678T>C p.L893P | Missense Mutation (SNP) | VAF 232/1569 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- PPARGC1B | c.1245G>T p.E415D | Missense Mutation (SNP) | VAF 102/346 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP3CA | c.1421A>G p.K474R | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRB1 | c.323C>A p.P108H | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); called by muse, mutect2
- PREP | c.1176del p.G393Afs*2 (on ENST00000369110; = p.G459Afs*2 on NM_002726.5) | Frame Shift Del (DEL) | VAF 40/160 reads (25%) | called by mutect2, pindel, varscan2
- PRRC2C | c.4920dup p.P1641Tfs*12 (on ENST00000367742; = p.P1639Tfs*12 on NM_015172.4) | Frame Shift Ins (INS) | VAF 64/234 reads (27%) | called by mutect2, pindel, varscan2
- PRUNE2 | c.2485A>G p.R829G | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.162); called by muse, mutect2
- PRUNE2 | c.1793dup p.E599Rfs*17 | Frame Shift Ins (INS) | VAF 46/160 reads (29%) | called by mutect2, pindel, varscan2
- PSME4 | c.2960A>G p.Q987R | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PYGM | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 158/561 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RAD51B | c.349T>G p.F117V | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- RCC2 | c.523G>A p.G175S | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RECQL4 | c.3097C>G p.L1033V | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- RGS12 | c.1180G>T p.G394C | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- RGS9 | c.1877C>T p.S626F | Missense Mutation (SNP) | VAF 116/322 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- RHBDL3 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 41/375 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RIMKLB | c.260G>T p.S87I | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- RNF213 | c.179dup p.C62Vfs*100 | Frame Shift Ins (INS) | VAF 150/511 reads (29%) | called by mutect2, pindel, varscan2
- RNF213 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RNF44 | c.1237-6C>T | Splice Region (SNP) | VAF 58/200 reads (29%) | called by muse, mutect2, varscan2
- RO60 | c.947del p.K316Rfs*10 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | called by mutect2, pindel, varscan2
- RPS26 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 99/469 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- RTL10 | c.124del p.V43Wfs*40 | Frame Shift Del (DEL) | VAF 87/461 reads (19%) | called by mutect2, pindel, varscan2
- RTN3 | c.3053del p.K1018Rfs*79 (on ENST00000377819 / NM_001265589.2; = p.K222Rfs*79 on NM_006054.4) | Frame Shift Del (DEL) | VAF 41/154 reads (27%) | called by mutect2, pindel, varscan2
- RYR1 | c.2252T>C p.V751A | Missense Mutation (SNP) | VAF 97/246 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- RYR1 | c.8580del p.D2861Tfs*67 | Frame Shift Del (DEL) | VAF 153/549 reads (28%) | called by mutect2, pindel, varscan2
- RYR2 | c.4189T>C p.Y1397H | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- SCAF11 | c.3002del p.N1001Mfs*5 | Frame Shift Del (DEL) | VAF 39/147 reads (27%) | called by mutect2, pindel, varscan2
- SETD3 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SF3B3 | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 79/289 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- SIM1 | c.620del p.N207Tfs*34 | Frame Shift Del (DEL) | VAF 59/294 reads (20%) | called by mutect2, pindel, varscan2
- SLC32A1 | c.578G>A p.C193Y | Missense Mutation (SNP) | VAF 102/353 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- SLC49A4 | c.433del p.R145Efs*3 | Frame Shift Del (DEL) | VAF 53/173 reads (31%) | called by mutect2, pindel, varscan2
- SLC66A1 | c.866T>C p.L289P | Missense Mutation (SNP) | VAF 14/273 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2
- SMARCAD1 | c.689del p.K230Rfs*28 | Frame Shift Del (DEL) | VAF 55/147 reads (37%) | called by mutect2, pindel, varscan2
- SMARCAD1 | c.2303del p.N768Tfs*8 | Frame Shift Del (DEL) | VAF 14/135 reads (10%) | called by mutect2, pindel
- SMTN | c.949del p.A318Pfs*39 | Frame Shift Del (DEL) | VAF 25/81 reads (31%) | called by mutect2, pindel, varscan2
- SOGA1 | c.2213C>T p.S738F | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SQSTM1 | c.1100T>C p.L367P | Missense Mutation (SNP) | VAF 100/282 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- STRN | c.1013del p.K338Rfs*9 | Frame Shift Del (DEL) | VAF 31/128 reads (24%) | called by mutect2, pindel, varscan2
- SYT13 | c.284_286del p.I95del | In Frame Del (DEL) | VAF 92/397 reads (23%) | called by pindel, varscan2
- TAS1R1 | c.2230G>A p.A744T | Missense Mutation (SNP) | VAF 90/312 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- TAZ | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 188/690 reads (27%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TCF12 | c.1836del p.K612Nfs*19 | Frame Shift Del (DEL) | VAF 96/388 reads (25%) | called by mutect2, pindel, varscan2
- TCTEX1D1 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TENM1 | c.8132C>T p.A2711V | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TENM4 | c.2323T>C p.C775R | Missense Mutation (SNP) | VAF 30/746 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2
- TEPP | c.500dup p.L168Afs*? | Frame Shift Ins (INS) | VAF 44/164 reads (27%) | called by mutect2, pindel, varscan2
- TFB1M | c.816G>T p.Q272H | Missense Mutation (SNP) | VAF 80/310 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TG | c.4124T>C p.I1375T | Missense Mutation (SNP) | VAF 14/398 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2
- TG | c.5335G>T p.G1779C | Missense Mutation (SNP) | VAF 17/500 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- TLR1 | c.275A>G p.N92S | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TLR9 | c.1451T>C p.L484P | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- TMPRSS11F | c.570G>A p.M190I | Missense Mutation (SNP) | VAF 93/229 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TNRC18 | c.3255dup p.A1086Sfs*28 | Frame Shift Ins (INS) | VAF 8/18 reads (44%) | called by mutect2, pindel, varscan2
- TOM1L1 | c.1009A>G p.M337V | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOP1MT | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 123/549 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TP53BP2 | c.275del p.P92Lfs*6 | Frame Shift Del (DEL) | VAF 40/91 reads (44%) | called by mutect2, pindel, varscan2
- TPBGL | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.041); called by muse, mutect2
- TSC2 | c.3116C>T p.T1039M | Missense Mutation (SNP) | VAF 298/762 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TSPAN12 | c.134T>C p.L45S | Missense Mutation (SNP) | VAF 51/253 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- TSPAN6 | c.277T>C p.Y93H | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TTC1 | c.218A>T p.E73V | Missense Mutation (SNP) | VAF 126/379 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBASH3B | c.1059G>T p.E353D | Missense Mutation (SNP) | VAF 92/262 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBB | c.313A>G p.K105E | Missense Mutation (SNP) | VAF 205/613 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, varscan2
- UHRF2 | c.837dup p.E280Rfs*12 | Frame Shift Ins (INS) | VAF 19/61 reads (31%) | called by mutect2, pindel, varscan2
- UNC13A | c.1376G>T p.R459L | Missense Mutation (SNP) | VAF 111/384 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- UROD | c.806T>C p.L269P | Missense Mutation (SNP) | VAF 19/428 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- USF3 | c.5615A>C p.E1872A | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- USP19 | c.2128G>A p.A710T | Missense Mutation (SNP) | VAF 70/298 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- USP36 | c.2306del p.P769Qfs*128 | Frame Shift Del (DEL) | VAF 56/165 reads (34%) | called by mutect2, pindel, varscan2
- UTS2B | c.62del p.S21Ifs*35 | Frame Shift Del (DEL) | VAF 30/107 reads (28%) | called by mutect2, pindel, varscan2
- UTS2R | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 16/345 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.019); called by muse, mutect2
- VARS1 | c.509_511del p.L170del | In Frame Del (DEL) | VAF 100/460 reads (22%) | called by pindel, varscan2
- VBP1 | c.66C>A p.H22Q | Missense Mutation (SNP) | VAF 85/279 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- VPS11 | c.266A>G p.N89S (on ENST00000620429; = p.N633S on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- VPS13D | c.8575A>C p.T2859P | Missense Mutation (SNP) | VAF 72/186 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, varscan2
- VPS39 | c.1559A>G p.Q520R (on ENST00000348544 / NM_001301138.2; = p.Q509R on NM_015289.5) | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.268); called by muse, mutect2
- WDR13 | c.1021A>G p.T341A | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- WDR81 | c.3542T>G p.L1181R (on ENST00000409644 / NM_001163809.2; = p.L130R on NM_152348.4) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- YLPM1 | c.761del p.P254Lfs*35 | Frame Shift Del (DEL) | VAF 48/204 reads (24%) | called by mutect2, pindel, varscan2
- ZCCHC4 | c.960dup p.E321* | Frame Shift Ins (INS) | VAF 26/80 reads (33%) | called by mutect2, varscan2
- ZDHHC19 | c.302T>C p.V101A | Missense Mutation (SNP) | VAF 76/209 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZDHHC23 | c.695G>A p.S232N | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- ZFP69 | c.194del p.P65Lfs*12 | Frame Shift Del (DEL) | VAF 34/147 reads (23%) | called by mutect2, pindel, varscan2
- ZFR | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 75/322 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.022); called by muse, varscan2
- ZIK1 | c.1437A>G p.I479M | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.201); called by muse, varscan2
- ZNF140 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ZNF157 | c.304_305del p.S102Tfs*11 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by pindel, varscan2
- ZNF268 | c.2096G>A p.S699N | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF277 | c.25dup p.A9Gfs*10 | Frame Shift Ins (INS) | VAF 86/366 reads (23%) | called by mutect2, pindel, varscan2
- ZNF34 | c.747del p.K249Nfs*75 | Frame Shift Del (DEL) | VAF 62/202 reads (31%) | called by mutect2, pindel, varscan2
- ZNF462 | c.6548C>T p.T2183I | Missense Mutation (SNP) | VAF 128/433 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF513 | c.696del p.T233Lfs*42 | Frame Shift Del (DEL) | VAF 32/292 reads (11%) | called by mutect2, pindel, varscan2
- ZNF696 | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 71/194 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ZNF736 | c.218A>T p.K73I | Missense Mutation (SNP) | VAF 102/450 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- ZNF841 | c.1964G>T p.G655V (on ENST00000426391 / NM_001369830.1; = p.G771V on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF845 | c.2244dup p.C749Mfs*2 | Frame Shift Ins (INS) | VAF 91/304 reads (30%) | called by mutect2, pindel, varscan2
- ZXDC | c.1132C>T p.H378Y | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACTL10 | c.153C>T p.T51= | Silent (SNP) | VAF 111/267 reads (42%) | called by muse, mutect2, varscan2
- AGMAT | c.333G>A p.T111= | Silent (SNP) | VAF 89/284 reads (31%) | catalogued as COSV101011826, COSV65435975; called by muse, mutect2, varscan2
- AL669918.1 | c.2349T>C p.N783= | Silent (SNP) | VAF 16/508 reads (3%) | called by muse, mutect2
- ALPI | c.1395G>A p.A465= | Silent (SNP) | VAF 20/454 reads (4%) | catalogued as rs867126363; called by muse, mutect2
- AMH | c.297C>A p.T99= | Silent (SNP) | VAF 22/66 reads (33%) | called by muse, mutect2, varscan2
- AOPEP | c.531G>T p.T177= | Silent (SNP) | VAF 85/306 reads (28%) | called by muse, mutect2, varscan2
- AP1M1 | c.1008C>T p.P336= | Silent (SNP) | VAF 56/152 reads (37%) | catalogued as rs775130446, COSV52224519; called by muse, mutect2, varscan2
- APBB2 | c.1038C>T p.N346= (on ENST00000295974 / NM_001166050.2; = p.N347= on NM_004307.2) | Silent (SNP) | VAF 52/139 reads (37%) | catalogued as rs757004371; called by muse, mutect2, varscan2
- ARHGAP6 | c.2901T>C p.D967= (on ENST00000337414 / NM_013427.3; = p.D764= on NM_013423.3) | Silent (SNP) | VAF 192/578 reads (33%) | called by muse, mutect2, varscan2
- ASB18 | c.987G>A p.P329= | Silent (SNP) | VAF 161/379 reads (42%) | catalogued as rs1318789332; called by muse, mutect2, varscan2
- ATP6V0D1 | c.198G>A p.T66= | Silent (SNP) | VAF 116/310 reads (37%) | catalogued as rs373076096; called by muse, mutect2, varscan2
- ATR | c.7470C>T p.C2490= | Silent (SNP) | VAF 41/120 reads (34%) | catalogued as rs574699024; called by muse, mutect2, varscan2
- ATRX | c.5655T>C p.H1885= | Silent (SNP) | VAF 93/228 reads (41%) | called by muse, mutect2, varscan2
- BAHCC1 | c.2320C>T p.L774= | Silent (SNP) | VAF 56/144 reads (39%) | called by muse, mutect2, varscan2
- BRINP1 | c.1962C>T p.D654= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as rs750068438, COSV56301767; called by muse, mutect2, varscan2
- CAMSAP1 | c.3315G>A p.A1105= | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as rs895709302, COSV100410438; called by muse, mutect2, varscan2
- CAMSAP3 | c.2805C>T p.A935= | Silent (SNP) | VAF 45/172 reads (26%) | catalogued as rs575495576; called by muse, mutect2, varscan2
- CD5L | c.426C>T p.D142= | Silent (SNP) | VAF 63/199 reads (32%) | catalogued as rs748603519, COSV63821204; called by muse, mutect2, varscan2
- CELA3B | c.87T>C p.V29= | Silent (SNP) | VAF 134/407 reads (33%) | called by muse, varscan2
- CKMT2 | c.828A>G p.K276= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as COSV99562403; called by muse, mutect2, varscan2
- COL13A1 | c.1485C>T p.H495= (on ENST00000398978 / NM_001130103.2; = p.H438= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/165 reads (24%) | catalogued as rs768223191, COSV62571289; called by muse, mutect2, varscan2
- CREBBP | c.732G>A p.T244= | Silent (SNP) | VAF 70/222 reads (32%) | catalogued as rs374065235, COSV52124229; called by muse, mutect2, varscan2
- DDX19B | c.822C>T p.S274= | Silent (SNP) | VAF 77/240 reads (32%) | catalogued as rs147242047; called by muse, mutect2, varscan2
- DMBT1 | c.1503C>T p.D501= | Silent (SNP) | VAF 158/485 reads (33%) | called by muse, mutect2, varscan2
- DMXL1 | c.8595A>T p.V2865= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as rs752059345; called by muse, mutect2, varscan2
- DNAJC2 | c.1626A>G p.E542= | Silent (SNP) | VAF 49/206 reads (24%) | catalogued as COSV50787592; called by muse, mutect2, varscan2
- DOCK5 | c.1659G>A p.K553= | Silent (SNP) | VAF 59/162 reads (36%) | catalogued as rs1477588687; called by muse, mutect2, varscan2
- DRD5 | c.465C>T p.R155= | Silent (SNP) | VAF 77/275 reads (28%) | catalogued as rs778933591; called by muse, mutect2, varscan2
- DUS3L | c.1077G>A p.E359= | Silent (SNP) | VAF 105/282 reads (37%) | called by muse, mutect2, varscan2
- EGR2 | c.507G>A p.P169= | Silent (SNP) | VAF 74/158 reads (47%) | catalogued as rs1060504688, COSV54348188; ClinVar: likely benign; called by muse, mutect2, varscan2
- EIF2B1 | c.91C>T p.L31= | Silent (SNP) | VAF 169/443 reads (38%) | called by muse, mutect2, varscan2
- EPB41L1 | c.984C>A p.S328= | Silent (SNP) | VAF 139/540 reads (26%) | catalogued as COSV99154313; called by muse, mutect2, varscan2
- ESX1 | c.435G>A p.A145= | Silent (SNP) | VAF 96/251 reads (38%) | catalogued as COSV101006493; called by muse, mutect2, varscan2
- FAM185A | c.702C>T p.T234= | Silent (SNP) | VAF 45/180 reads (25%) | catalogued as rs945662058, COSV101316198, COSV68644736; called by muse, mutect2, varscan2
- FARP2 | c.2923C>T p.L975= | Silent (SNP) | VAF 65/175 reads (37%) | catalogued as COSV50869253; called by muse, mutect2, varscan2
- FBXO40 | c.183G>A p.E61= | Silent (SNP) | VAF 85/209 reads (41%) | called by muse, mutect2, varscan2
- FLI1 | c.1257A>C p.A419= | Silent (SNP) | VAF 144/419 reads (34%) | catalogued as rs774514059; called by muse, mutect2, varscan2
- FOXE1 | c.522C>T p.A174= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs1237247479; called by muse, mutect2
- GABBR1 | c.1404G>A p.P468= | Silent (SNP) | VAF 102/305 reads (33%) | catalogued as rs186263204; ClinVar: benign; called by muse, mutect2, varscan2
- GALNT7 | c.1509A>G p.E503= | Silent (SNP) | VAF 89/278 reads (32%) | catalogued as rs1210963717; called by muse, mutect2, varscan2
- GAS2L3 | c.1518T>C p.N506= | Silent (SNP) | VAF 65/240 reads (27%) | called by muse, mutect2, varscan2
- GFI1 | c.522C>T p.A174= | Silent (SNP) | VAF 70/244 reads (29%) | called by muse, mutect2, varscan2
- GGNBP2 | c.213C>T p.A71= | Silent (SNP) | VAF 119/323 reads (37%) | called by muse, mutect2, varscan2
- GIGYF1 | c.774A>G p.R258= | Silent (SNP) | VAF 36/159 reads (23%) | called by muse, mutect2, varscan2
- GJA3 | c.1074C>T p.S358= | Silent (SNP) | VAF 8/200 reads (4%) | called by muse, mutect2
- GTF3A | c.1008G>A p.G336= | Silent (SNP) | VAF 36/166 reads (22%) | called by muse, mutect2, varscan2
- HRH2 | c.513C>A p.T171= | Silent (SNP) | VAF 92/249 reads (37%) | catalogued as COSV99199830; called by muse, mutect2, varscan2
- IDH1 | c.900C>T p.G300= | Silent (SNP) | VAF 116/399 reads (29%) | called by muse, mutect2, varscan2
- INA | c.552G>A p.E184= | Silent (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- INPP4A | c.1341A>G p.T447= | Silent (SNP) | VAF 29/90 reads (32%) | called by muse, mutect2, varscan2
- IQSEC3 | c.1494C>T p.S498= (on ENST00000538872 / NM_001170738.2; = p.S195= on NM_015232.1) | Silent (SNP) | VAF 76/240 reads (32%) | catalogued as rs782446042; called by muse, mutect2, varscan2
- JADE3 | c.1251C>T p.A417= | Silent (SNP) | VAF 15/297 reads (5%) | catalogued as rs781815416; called by muse, mutect2
- KBTBD13 | c.1005G>A p.E335= | Silent (SNP) | VAF 67/666 reads (10%) | catalogued as rs1281563568; called by muse, mutect2
- KCNH5 | c.210G>A p.G70= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV100526945; called by muse, mutect2, varscan2
- KITLG | c.360T>C p.S120= | Silent (SNP) | VAF 27/96 reads (28%) | called by muse, mutect2, varscan2
- KPTN | c.828C>T p.L276= | Silent (SNP) | VAF 117/357 reads (33%) | catalogued as rs750017002; called by muse, mutect2, varscan2
- LAMA5 | c.8001G>A p.L2667= | Silent (SNP) | VAF 65/174 reads (37%) | called by muse, mutect2, varscan2
- LEF1 | c.36G>C p.G12= | Silent (SNP) | VAF 76/185 reads (41%) | catalogued as rs766540959, COSV54469505; called by muse, mutect2, varscan2
- LRRN4 | c.2064C>T p.C688= | Silent (SNP) | VAF 71/204 reads (35%) | catalogued as COSV66646623; called by muse, mutect2, varscan2
- LTBP4 | c.1149C>T p.C383= (on ENST00000308370 / NM_001042544.1; = p.C346= on NM_003573.2) | Silent (SNP) | VAF 65/205 reads (32%) | called by muse, mutect2, varscan2
- MESP2 | c.819G>A p.T273= | Silent (SNP) | VAF 89/239 reads (37%) | catalogued as rs1482818795; called by muse, mutect2, varscan2
- MET | c.1626C>T p.H542= | Silent (SNP) | VAF 21/300 reads (7%) | catalogued as rs762898756; ClinVar: likely benign; called by muse, mutect2
- MFAP2 | c.42C>A p.G14= | Silent (SNP) | VAF 65/185 reads (35%) | called by muse, mutect2, varscan2
- N6AMT1 | c.645G>A p.*215= | Silent (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- NDC1 | c.547C>T p.L183= | Silent (SNP) | VAF 43/132 reads (33%) | catalogued as rs778740224; called by muse, mutect2, varscan2
- NEFL | c.585G>A p.A195= | Silent (SNP) | VAF 139/334 reads (42%) | catalogued as rs1377847387, COSV55338732; called by muse, mutect2, varscan2
- NKAP | c.291G>A p.S97= | Silent (SNP) | VAF 77/232 reads (33%) | catalogued as COSV101004186; called by muse, mutect2, varscan2
- NPAT | c.2256A>G p.S752= | Silent (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- NPBWR1 | c.195G>A p.A65= | Silent (SNP) | VAF 140/342 reads (41%) | called by muse, varscan2
- NTF3 | c.291A>G p.R97= | Silent (SNP) | VAF 89/267 reads (33%) | called by muse, mutect2
- NTPCR | c.9G>A p.R3= | Silent (SNP) | VAF 19/65 reads (29%) | called by muse, mutect2
- OR56B4 | c.847C>T p.L283= | Silent (SNP) | VAF 78/346 reads (23%) | catalogued as rs374576079; called by muse, mutect2
- OR6C65 | c.252T>C p.A84= | Silent (SNP) | VAF 31/88 reads (35%) | called by muse, mutect2, varscan2
- OR6K6 | c.801C>A p.T267= (on ENST00000368144; = p.T243= on NM_001005184.1) | Silent (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- ORC5 | c.888G>A p.A296= | Silent (SNP) | VAF 63/127 reads (50%) | catalogued as rs377574889; called by muse, mutect2, varscan2
- OTUD6A | c.840C>T p.A280= | Silent (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- PABPC5 | c.90C>T p.T30= | Silent (SNP) | VAF 83/225 reads (37%) | catalogued as rs1283519732, COSV57041738; called by muse, mutect2, varscan2
- PARP1 | c.831G>A p.S277= | Silent (SNP) | VAF 110/412 reads (27%) | catalogued as rs750442044, COSV100828830; called by muse, mutect2, varscan2
- PCDH10 | c.1953G>A p.Q651= | Silent (SNP) | VAF 25/85 reads (29%) | called by muse, mutect2, varscan2
- PCDHA2 | c.1245C>T p.R415= | Silent (SNP) | VAF 142/430 reads (33%) | catalogued as COSV100973632; called by muse, varscan2
- PCDHB12 | c.1614C>T p.S538= | Silent (SNP) | VAF 44/912 reads (5%) | catalogued as COSV99507508; called by muse, mutect2
- PHF6 | c.426A>G p.L142= (on ENST00000332070 / NM_032458.3; = p.L143= on NM_032335.3) | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV100136380; called by muse, mutect2, varscan2
- PIK3C2B | c.3813C>T p.H1271= | Silent (SNP) | VAF 65/204 reads (32%) | catalogued as rs1558234031; called by muse, mutect2, varscan2
- PLEKHA7 | c.996T>C p.I332= | Silent (SNP) | VAF 117/335 reads (35%) | catalogued as rs1468048025; called by muse, mutect2, varscan2
- POTEJ | c.273C>T p.F91= | Silent (SNP) | VAF 138/561 reads (25%) | called by muse, mutect2, varscan2
- PPFIA4 | c.1548C>T p.D516= (on ENST00000447715; = p.D491= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 85/287 reads (30%) | catalogued as rs575104032, COSV55317076; called by muse, mutect2, varscan2
- PRDM16 | c.993C>T p.H331= | Silent (SNP) | VAF 92/258 reads (36%) | catalogued as rs374504712; called by muse, mutect2, varscan2
- PREX2 | c.1875T>C p.A625= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs765012448; called by muse, mutect2, varscan2
- PRG4 | c.4089C>T p.D1363= | Silent (SNP) | VAF 53/169 reads (31%) | catalogued as rs145515394; called by muse, mutect2, varscan2
- PROSER1 | c.1752C>T p.G584= | Silent (SNP) | VAF 90/257 reads (35%) | called by muse, mutect2, varscan2
- PRPF31 | c.861G>A p.L287= | Silent (SNP) | VAF 18/587 reads (3%) | called by muse, mutect2
- PRRT3 | c.2340C>T p.R780= | Silent (SNP) | VAF 74/212 reads (35%) | catalogued as rs1374415391, COSV55978340; called by muse, mutect2, varscan2
- PTPRH | c.483C>T p.G161= | Silent (SNP) | VAF 126/421 reads (30%) | catalogued as COSV99670957; called by muse, mutect2, varscan2
- RASA3 | c.1962G>A p.A654= | Silent (SNP) | VAF 82/251 reads (33%) | catalogued as rs761708403, COSV61868584; called by muse, mutect2, varscan2
- RBM43 | c.984T>C p.Y328= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as rs1173817629; called by muse, mutect2, varscan2
- RCVRN | c.597C>T p.N199= | Silent (SNP) | VAF 40/116 reads (34%) | catalogued as rs747227351; called by muse, varscan2
- RETSAT | c.1125G>A p.K375= | Silent (SNP) | VAF 38/96 reads (40%) | called by muse, mutect2, varscan2
- RTEL1 | c.2055G>A p.Q685= | Silent (SNP) | VAF 13/311 reads (4%) | catalogued as COSV58893023; called by muse, mutect2
- SDF4 | c.1053G>A p.V351= | Silent (SNP) | VAF 39/108 reads (36%) | catalogued as rs1209127760; called by muse, mutect2, varscan2
- SETD3 | c.489T>C p.C163= | Silent (SNP) | VAF 76/245 reads (31%) | called by muse, mutect2, varscan2
- SF1 | c.1026C>T p.S342= | Silent (SNP) | VAF 36/128 reads (28%) | catalogued as rs753308456, COSV57113121; called by muse, mutect2, varscan2
- SGCZ | c.27T>C p.I9= | Silent (SNP) | VAF 80/217 reads (37%) | catalogued as COSV101170169; called by muse, mutect2, varscan2
- SH3BP4 | c.2043C>T p.D681= | Silent (SNP) | VAF 91/235 reads (39%) | catalogued as rs774364587; called by muse, mutect2, varscan2
- SLC7A9 | c.1032C>A p.I344= | Silent (SNP) | VAF 121/373 reads (32%) | called by muse, mutect2, varscan2
- SOX8 | c.966G>A p.P322= | Silent (SNP) | VAF 106/261 reads (41%) | catalogued as rs754519733; called by muse, mutect2, varscan2
- SPTBN4 | c.6717C>T p.R2239= | Silent (SNP) | VAF 114/293 reads (39%) | called by muse, mutect2, varscan2
- STIL | c.1746A>G p.G582= | Silent (SNP) | VAF 47/156 reads (30%) | called by muse, mutect2, varscan2
- STOX1 | c.1209G>A p.G403= | Silent (SNP) | VAF 46/186 reads (25%) | called by muse, mutect2, varscan2
- SUPT5H | c.264C>T p.D88= | Silent (SNP) | VAF 67/153 reads (44%) | catalogued as rs752398773, COSV100782163; called by muse, mutect2, varscan2
- SYNE2 | c.18030C>T p.I6010= | Silent (SNP) | VAF 41/228 reads (18%) | catalogued as rs145549349, COSV59966672; called by muse, mutect2, varscan2
- SYNPO2L | c.960C>T p.G320= (on ENST00000394810 / NM_001114133.3; = p.G96= on NM_024875.5) | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as rs576909291; called by muse, mutect2, varscan2
- TECPR1 | c.723C>A p.T241= | Silent (SNP) | VAF 71/302 reads (24%) | called by muse, mutect2, varscan2
- TENM4 | c.2028C>T p.G676= | Silent (SNP) | VAF 97/272 reads (36%) | catalogued as rs747289427, COSV53609426; called by muse, mutect2, varscan2
- TEX14 | c.1614C>T p.P538= (on ENST00000240361 / NM_001201457.2; = p.P532= on NM_031272.5) | Silent (SNP) | VAF 35/133 reads (26%) | catalogued as rs56213417; called by muse, mutect2, varscan2
- TEX9 | c.498G>T p.G166= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs376599048; called by muse, mutect2, varscan2
- TNRC18 | c.6597G>C p.R2199= | Silent (SNP) | VAF 50/99 reads (51%) | called by muse, mutect2, varscan2
- TPO | c.1158C>T p.R386= | Silent (SNP) | VAF 162/482 reads (34%) | called by muse, mutect2, varscan2
- TRIO | c.7389C>T p.S2463= | Silent (SNP) | VAF 89/281 reads (32%) | catalogued as rs1358661971; called by muse, mutect2, varscan2
- TSC2 | c.1932C>T p.C644= | Silent (SNP) | VAF 180/575 reads (31%) | catalogued as rs777665839; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- TWNK | c.1875C>A p.S625= | Silent (SNP) | VAF 47/429 reads (11%) | called by muse, mutect2, varscan2
- UFL1 | c.1668A>G p.K556= | Silent (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- UGGT1 | c.4224C>T p.A1408= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as rs369076894; called by muse, mutect2
- UNC45A | c.1800T>C p.Y600= | Silent (SNP) | VAF 62/178 reads (35%) | catalogued as COSV67816467; called by muse, mutect2, varscan2
- USP9X | c.1878C>T p.S626= | Silent (SNP) | VAF 41/109 reads (38%) | called by muse, mutect2, varscan2
- VGLL1 | c.369C>A p.A123= | Silent (SNP) | VAF 104/376 reads (28%) | catalogued as rs371510040; called by muse, mutect2, varscan2
- VPS35L | c.2544C>T p.S848= | Silent (SNP) | VAF 94/233 reads (40%) | called by muse, mutect2, varscan2
- ZCCHC2 | c.474G>C p.P158= | Silent (SNP) | VAF 88/255 reads (35%) | catalogued as rs1036970736; called by muse, mutect2, varscan2
- ZCCHC2 | c.3504C>T p.P1168= | Silent (SNP) | VAF 71/216 reads (33%) | catalogued as COSV99502660; called by muse, mutect2, varscan2
- ZIC5 | c.1257G>A p.P419= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as rs529577435, COSV57438611; called by muse, mutect2, varscan2
- ZNF468 | c.807A>G p.K269= | Silent (SNP) | VAF 68/212 reads (32%) | catalogued as rs1488787053; called by muse, mutect2, varscan2
- ZNF561 | c.1143T>C p.I381= | Silent (SNP) | VAF 44/104 reads (42%) | called by muse, mutect2, varscan2
- ZNF667 | c.1617C>T p.R539= | Silent (SNP) | VAF 39/206 reads (19%) | catalogued as COSV52640773; called by muse, mutect2, varscan2
- ZNF789 | c.1221G>A p.K407= | Silent (SNP) | VAF 37/178 reads (21%) | called by muse, mutect2, varscan2
- ZNF862 | c.699G>A p.P233= | Silent (SNP) | VAF 72/445 reads (16%) | catalogued as rs375533066; called by muse, mutect2, varscan2
- ZNF862 | c.2358G>A p.A786= | Silent (SNP) | VAF 18/520 reads (3%) | catalogued as rs1437573424; called by muse, mutect2
- ZSCAN2 | c.165C>A p.P55= | Silent (SNP) | VAF 64/301 reads (21%) | called by muse, mutect2, varscan2
- AC073348.1 | n.167del | RNA (DEL) | VAF 36/180 reads (20%) | catalogued as rs761017316; called by mutect2, pindel, varscan2
- ACAD9 | c.*382T>C | 3'UTR (SNP) | VAF 72/190 reads (38%) | called by muse, mutect2, varscan2
- ACTA1 | c.*31A>G | 3'UTR (SNP) | VAF 119/333 reads (36%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845776 ins G | 5'Flank (INS) | VAF 47/167 reads (28%) | called by mutect2, pindel, varscan2
- APOC1P1 | n.480C>A | RNA (SNP) | VAF 49/120 reads (41%) | called by muse, mutect2, varscan2
- ARID5A | c.313-24C>T | Intron (SNP) | VAF 81/459 reads (18%) | catalogued as rs763163740; called by muse, mutect2, varscan2
- B3GALT5-AS1 | chr21:39597879 T>C | 3'Flank (SNP) | VAF 159/449 reads (35%) | called by muse, mutect2, varscan2
- C1orf109 | c.-4+95A>G | Intron (SNP) | VAF 49/119 reads (41%) | called by muse, mutect2
- C8orf58 | c.767-24G>A | Intron (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2, varscan2
- CATSPER2 | c.-86-41G>A | Intron (SNP) | VAF 20/77 reads (26%) | catalogued as rs1170121736; called by muse, mutect2, varscan2
- CATSPER4 | c.*51G>A | 3'UTR (SNP) | VAF 55/201 reads (27%) | catalogued as rs548868450; called by muse, mutect2, varscan2
- CFAP44 | chr3:113358861 del ATCTACATCAAAAT | 3'Flank (DEL) | VAF 45/141 reads (32%) | called by mutect2, pindel, varscan2
- CLEC16A | c.2641+15del | Intron (DEL) | VAF 153/555 reads (28%) | called by mutect2, pindel, varscan2
- CNTN1 | c.-34del | 5'UTR (DEL) | VAF 19/76 reads (25%) | called by mutect2, pindel, varscan2
- CNTNAP3P2 | n.1203A>G | RNA (SNP) | VAF 163/293 reads (56%) | called by muse, mutect2, varscan2
- COQ9 | c.522-38del | Intron (DEL) | VAF 58/205 reads (28%) | called by mutect2, pindel, varscan2
- CPSF4 | c.*71C>T | 3'UTR (SNP) | VAF 149/484 reads (31%) | called by muse, mutect2, varscan2
- CSGALNACT1 | c.*539C>T | 3'UTR (SNP) | VAF 26/79 reads (33%) | called by muse, mutect2, varscan2
- CSNK2B | c.72+246del | Intron (DEL) | VAF 53/171 reads (31%) | catalogued as rs761333449; called by mutect2, varscan2
- CTBP2 | c.58+12145C>T | Intron (SNP) | VAF 124/342 reads (36%) | called by muse, mutect2, varscan2
- CTDSP1 | c.-52del | 5'UTR (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel
- CXADRP2 | n.608G>A | RNA (SNP) | VAF 39/236 reads (17%) | catalogued as rs763811297; called by muse, mutect2, varscan2
- CYBA | c.369+768G>A | Intron (SNP) | VAF 91/417 reads (22%) | catalogued as rs781421461; called by muse, mutect2, varscan2
- CYP27A1 | c.1184+31G>A | Intron (SNP) | VAF 111/327 reads (34%) | called by muse, mutect2, varscan2
- DECR2 | c.149+570C>T | Intron (SNP) | VAF 30/174 reads (17%) | called by muse, mutect2, varscan2
- DISP1 | c.890-12del | Intron (DEL) | VAF 32/90 reads (36%) | catalogued as rs546218400; called by mutect2, varscan2
- DNMT1 | c.3901-30G>A | Intron (SNP) | VAF 44/124 reads (35%) | catalogued as rs368933609; called by muse, mutect2, varscan2
- DST | c.4297-1349A>G | Intron (SNP) | VAF 112/360 reads (31%) | called by muse, mutect2, varscan2
- DST | c.4296+4308del | Intron (DEL) | VAF 44/181 reads (24%) | called by mutect2, pindel, varscan2
- EAF1 | c.761-15T>A | Intron (SNP) | VAF 24/88 reads (27%) | catalogued as rs367733616; called by mutect2, varscan2
- EAPP | c.74+176del | Intron (DEL) | VAF 63/248 reads (25%) | catalogued as COSV51653540; called by mutect2, pindel, varscan2
- EEF2 | c.613-60C>T | Intron (SNP) | VAF 122/308 reads (40%) | catalogued as rs767943834; called by muse, mutect2, varscan2
- EFHB | chr3:19936145 A>T | 5'Flank (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- EIF2A | c.476-3del | Intron (DEL) | VAF 5/19 reads (26%) | catalogued as rs769244111; called by mutect2, varscan2
- EMG1 | c.413-12del | Intron (DEL) | VAF 47/276 reads (17%) | called by mutect2, pindel, varscan2
- EPS8L1 | c.430-223C>T | Intron (SNP) | VAF 32/104 reads (31%) | called by muse, mutect2, varscan2
- F11 | c.1577-11del | Intron (DEL) | VAF 74/202 reads (37%) | catalogued as rs776438459; called by mutect2, pindel, varscan2
- FAM131A | chr3:184338655 C>T | 5'Flank (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- FAM217A | c.-18_-17del | 5'UTR (DEL) | VAF 42/220 reads (19%) | catalogued as rs1303432769; called by pindel, varscan2
- FAM228B | c.932+1069A>G | Intron (SNP) | VAF 79/273 reads (29%) | called by muse, mutect2, varscan2
- FAM74A7 | n.679T>C | RNA (SNP) | VAF 8/127 reads (6%) | called by muse, mutect2
- FANCM | c.681+28T>C | Intron (SNP) | VAF 44/120 reads (37%) | called by muse, mutect2, varscan2
- GLB1 | c.1233+44A>G | Intron (SNP) | VAF 12/207 reads (6%) | called by muse, mutect2
- GNAI1 | c.-19G>T | 5'UTR (SNP) | VAF 28/89 reads (31%) | called by muse, mutect2, varscan2
- GSN-AS1 | n.3751G>T | RNA (SNP) | VAF 126/322 reads (39%) | called by muse, mutect2, varscan2
70 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 70 other) are not listed here.
